Somatic mutation profile of tumor specimen MMRF_1850_1_BM_CD138pos (aliquot MMRF_1850_1_BM_CD138pos_T1_KBS5U_L06425) from MMRF case MMRF_1850, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.7 years (20,358 days).
Specimen MMRF_1850_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3e24223-75c2-4620-9ea3-1850b938e032.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1850_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1850_1_PB_Whole_C3_KBS5U_L06471; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ccc5b981-d94c-45de-823f-11bd21f8d3da

The open-access MAF lists 103 somatic variants for this specimen: 45 protein-altering or splice-affecting, 9 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, 3'UTR 30, Intron 13, Silent 9, Frame Shift Ins 3, 3'Flank 2, 5'Flank 2, 5'UTR 2, Frame Shift Del 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 127/306 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ABCB8 | c.570G>C p.E190D (on ENST00000297504 / NM_001282291.2; = p.E173D on NM_007188.5) | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.09); catalogued as COSV52503878; called by muse, mutect2, varscan2
- CACNA2D4 | c.1373C>T p.T458M | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373696894; called by muse, mutect2, varscan2
- COL24A1 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs774357164, COSV65311296; called by muse, mutect2, varscan2
- CYTH3 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 50/76 reads (66%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.885); catalogued as rs375159013; called by muse, mutect2, varscan2
- ECRG4 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1369596728, COSV53001627; called by muse, mutect2, varscan2
- IGHJ4 | c.31G>T p.V11F | Missense Mutation (SNP) | VAF 29/34 reads (85%) | PolyPhen possibly damaging (0.577); catalogued as rs377431969; called by muse, mutect2, varscan2
- IGHV2-70 | c.91G>C p.V31L | Missense Mutation (SNP) | VAF 45/68 reads (66%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs373084365; called by muse, varscan2
- IGHV3-7 | c.17G>A p.S6N | Missense Mutation (SNP) | VAF 68/131 reads (52%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs572360030; called by muse, mutect2, varscan2
- IGKV4-1 | c.305G>C p.S102T | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as rs369753146; called by muse, mutect2
- MDFIC | c.106A>G p.K36E | Missense Mutation (SNP) | VAF 112/354 reads (32%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as rs750119821; called by muse, mutect2, varscan2
- MECOM | c.641G>T p.R214I (on ENST00000468789 / NM_001105078.4; = p.R402I on NM_004991.4) | Missense Mutation (SNP) | VAF 15/236 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52963605; called by muse, mutect2
- RASA1 | c.2406G>C p.M802I | Missense Mutation (SNP) | VAF 66/243 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57192907, COSV57198698; called by muse, mutect2, varscan2
- RBM6 | c.129C>G p.H43Q | Missense Mutation (SNP) | VAF 17/375 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.959); catalogued as rs1356802561; called by muse, mutect2
- SCGN | c.464G>A p.G155D | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100618892; called by muse, mutect2, varscan2
- SEMA5B | c.990C>A p.F330L | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.93); catalogued as COSV52103555; called by muse, mutect2, varscan2
- ABCA8 | c.623dup p.N208Kfs*16 | Frame Shift Ins (INS) | VAF 23/65 reads (35%) | called by mutect2, pindel, varscan2
- AHNAK | c.13796A>G p.D4599G | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2
- ANGPTL5 | c.758C>T p.T253I | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- ARID1A | c.4739del p.N1580Ifs*32 | Frame Shift Del (DEL) | VAF 55/126 reads (44%) | called by mutect2, pindel, varscan2
- ASTN2 | c.3089T>A p.L1030Q (on ENST00000313400 / NM_001365069.1; = p.L979Q on NM_014010.5) | Missense Mutation (SNP) | VAF 82/275 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- C10orf67 | c.1523A>C p.H508P | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- CHSY1 | c.346A>G p.K116E | Missense Mutation (SNP) | VAF 97/214 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CNNM3 | c.1591A>G p.N531D | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- CRTC3 | c.489T>G p.D163E | Missense Mutation (SNP) | VAF 76/375 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DKC1 | c.569T>G p.V190G | Missense Mutation (SNP) | VAF 69/75 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DST | c.20675T>G p.I6892S (on ENST00000361203 / NM_001374722.1; = p.I4589S on NM_015548.5) | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- GFAP | c.1378-1G>A p.X460_splice (on ENST00000253408 / NM_001363846.2; = p.X420_splice on NM_002055.5) | Splice Site (SNP) | VAF 22/63 reads (35%) | called by muse, mutect2, varscan2
- HCFC2 | c.784G>A p.G262R | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HEATR1 | c.3820C>G p.P1274A | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HECTD1 | c.2256dup p.L753Tfs*20 | Frame Shift Ins (INS) | VAF 11/117 reads (9%) | called by mutect2, pindel
- KLHL15 | c.876C>G p.S292R | Missense Mutation (SNP) | VAF 61/66 reads (92%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LUZP2 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 75/284 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MAN2C1 | c.748C>G p.Q250E | Missense Mutation (SNP) | VAF 35/239 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- NR3C2 | c.632A>T p.N211I | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCDHGB3 | c.1366T>G p.S456A | Missense Mutation (SNP) | VAF 85/310 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RALGAPA2 | c.2111A>T p.D704V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- SLC26A3 | c.120A>C p.K40N | Missense Mutation (SNP) | VAF 53/83 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- SPAG9 | c.1276G>C p.A426P (on ENST00000262013 / NM_001130528.3; = p.A412P on NM_003971.6) | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TASOR2 | c.6547A>G p.S2183G | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TENT5C | c.693_702dup p.N235Rfs*52 | Frame Shift Ins (INS) | VAF 44/126 reads (35%) | called by mutect2, varscan2
- TMEM260 | c.38A>T p.D13V | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZC3H13 | c.4478T>A p.L1493* (on ENST00000242848 / NM_001330565.2; = p.L1494* on NM_015070.6) | Nonsense Mutation (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
- ZFPL1 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 51/204 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF792 | c.455C>T p.T152I | Missense Mutation (SNP) | VAF 47/183 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATP11A | c.2091G>A p.T697= | Silent (SNP) | VAF 45/89 reads (51%) | catalogued as rs533028763, COSV52108032; called by muse, mutect2, varscan2
- ATP6V0A1 | c.2388C>G p.L796= (on ENST00000343619 / NM_001378531.1; = p.L790= on NM_005177.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 27/71 reads (38%) | called by muse, mutect2, varscan2
- DCHS1 | c.207G>A p.P69= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as rs751442227; called by muse, mutect2, varscan2
- EYS | c.5382T>C p.Y1794= | Silent (SNP) | VAF 9/134 reads (7%) | called by muse, mutect2
- IGHV2-70 | c.54A>G p.L18= | Silent (SNP) | VAF 40/72 reads (56%) | catalogued as rs187704106; called by muse, varscan2
- IGKJ3 | c.24C>T p.T8= | Silent (SNP) | VAF 60/118 reads (51%) | catalogued as rs186782281; called by muse, varscan2
- NLRP5 | c.693C>T p.D231= | Silent (SNP) | VAF 56/80 reads (70%) | catalogued as rs1276751875; called by muse, mutect2, varscan2
- NMUR2 | c.402C>T p.I134= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as rs1380571024; called by muse, mutect2, varscan2
- SOCS6 | c.402C>T p.P134= | Silent (SNP) | VAF 51/118 reads (43%) | catalogued as rs201422335; called by muse, mutect2, varscan2
- ADAM15 | c.745-16C>T | Intron (SNP) | VAF 62/134 reads (46%) | called by muse, mutect2, varscan2
- ADD1 | c.*251A>G | 3'UTR (SNP) | VAF 6/142 reads (4%) | catalogued as rs1376300178; called by muse, mutect2
- ASCC3 | c.*258T>G | 3'UTR (SNP) | VAF 26/59 reads (44%) | called by muse, mutect2, varscan2
- BPNT2 | c.*558T>A | 3'UTR (SNP) | VAF 53/118 reads (45%) | called by muse, mutect2, varscan2
- CACNA2D2 | chr3:50364121 G>A | 3'Flank (SNP) | VAF 20/91 reads (22%) | called by muse, mutect2, varscan2
- CBLN2 | c.358-82G>A | Intron (SNP) | VAF 9/109 reads (8%) | called by muse, mutect2
- CHRDL1 | c.*228G>A | 3'UTR (SNP) | VAF 20/20 reads (100%) | called by muse, mutect2, varscan2
- COL4A3 | c.*1584G>T | 3'UTR (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
- CROCCP2 | n.495+7941C>A | Intron (SNP) | VAF 25/130 reads (19%) | called by muse, mutect2, varscan2
- DST | c.4297-2503C>T | Intron (SNP) | VAF 46/105 reads (44%) | catalogued as rs776792224; called by muse, mutect2, varscan2
- EIF2AK2 | c.*5485_*5486del | 3'UTR (DEL) | VAF 20/63 reads (32%) | called by mutect2, pindel, varscan2
- ERBB4 | c.*2667del | 3'UTR (DEL) | VAF 18/34 reads (53%) | catalogued as rs910580728; called by mutect2, varscan2
- ERLIN2 | chr8:37736476 C>A | 5'Flank (SNP) | VAF 31/86 reads (36%) | called by muse, mutect2, varscan2
- EYA3 | c.*2100T>C | 3'UTR (SNP) | VAF 57/118 reads (48%) | called by muse, mutect2, varscan2
- FABP2 | c.*152G>C | 3'UTR (SNP) | VAF 74/158 reads (47%) | called by muse, mutect2, varscan2
- FAM102A | c.*1904G>A | 3'UTR (SNP) | VAF 44/157 reads (28%) | called by muse, mutect2
- FAM149A | c.2248+261A>G | Intron (SNP) | VAF 19/34 reads (56%) | called by muse, mutect2, varscan2
- FAM83H | c.*1578C>T | 3'UTR (SNP) | VAF 26/67 reads (39%) | catalogued as rs781800171; called by muse, mutect2, varscan2
- GPR135 | c.*1412A>G | 3'UTR (SNP) | VAF 5/81 reads (6%) | called by muse, mutect2
- GTF2H5 | c.*959C>T | 3'UTR (SNP) | VAF 11/25 reads (44%) | called by muse, varscan2
- HERC2 | c.*116G>A | 3'UTR (SNP) | VAF 42/181 reads (23%) | called by muse, mutect2, varscan2
- IGLL5 | c.-94G>A | 5'UTR (SNP) | VAF 31/62 reads (50%) | catalogued as rs543881324, COSV73250507, COSV73251142; called by muse, mutect2, varscan2
- IRF8 | c.174+61G>A | Intron (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- KATNAL1 | c.*4922A>C | 3'UTR (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
- KIF25 | c.317+2057G>C | Intron (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- LARS1 | c.*844T>G | 3'UTR (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- LMO4 | chr1:87346698 A>T | 3'Flank (SNP) | VAF 31/78 reads (40%) | called by muse, mutect2, varscan2
- LSM11 | c.*5309C>G | 3'UTR (SNP) | VAF 32/102 reads (31%) | called by muse, mutect2, varscan2
- LSM5 | c.*1308T>G | 3'UTR (SNP) | VAF 7/22 reads (32%) | catalogued as rs1336760658; called by muse, varscan2
- MGAM | c.4618+322T>C | Intron (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- MGST1 | c.*68T>A | 3'UTR (SNP) | VAF 6/130 reads (5%) | called by muse, mutect2
- P2RX5 | chr17:3696182 A>C | 5'Flank (SNP) | VAF 25/55 reads (45%) | called by muse, mutect2, varscan2
- PAPOLA | c.-71del | 5'UTR (DEL) | VAF 10/32 reads (31%) | called by mutect2, pindel, varscan2
- POLR2J | c.*223C>T | 3'UTR (SNP) | VAF 8/107 reads (7%) | catalogued as rs1001361022; called by muse, mutect2
- PPP2R5C | c.1151+39_1151+45del | Intron (DEL) | VAF 64/147 reads (44%) | called by mutect2, pindel, varscan2
- PTPRK | c.495+486T>G | Intron (SNP) | VAF 22/46 reads (48%) | called by muse, mutect2, varscan2
- PTTG1IP | c.*1559A>G | 3'UTR (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- SEC24D | c.*441T>A | 3'UTR (SNP) | VAF 24/40 reads (60%) | called by muse, varscan2
- SEC24D | c.*369C>T | 3'UTR (SNP) | VAF 32/60 reads (53%) | called by muse, varscan2
- SERAC1 | c.*328G>A | 3'UTR (SNP) | VAF 35/81 reads (43%) | called by muse, mutect2, varscan2
- SERPINH1 | c.954+204C>T | Intron (SNP) | VAF 79/129 reads (61%) | catalogued as rs1035438773; called by muse, mutect2, varscan2
- SNX19 | c.*403A>C | 3'UTR (SNP) | VAF 105/307 reads (34%) | called by muse, mutect2, varscan2
- TNFSF8 | c.*604G>A | 3'UTR (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- TRIM59 | c.*193A>G | 3'UTR (SNP) | VAF 26/125 reads (21%) | called by muse, mutect2, varscan2
- UCN2 | c.*560G>T | 3'UTR (SNP) | VAF 102/153 reads (67%) | called by muse, mutect2, varscan2
- WNT5A | c.*3911dup | 3'UTR (INS) | VAF 16/50 reads (32%) | called by mutect2, varscan2
- ZFP36L1 | c.*7-355G>A | Intron (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- ZNF791 | c.*1684dup | 3'UTR (INS) | VAF 15/61 reads (25%) | called by mutect2, pindel, varscan2
- ZNF846 | c.16-12T>G | Intron (SNP) | VAF 5/73 reads (7%) | called by muse, mutect2
